Surgical pathology report (de-identified scan), TCGA case TCGA-58-8392, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-8392-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

Lung, left, upper lobe: 19.0 x 17.0 x 5.5 cm

Tumor: 4.8 x 4.2 x 3.8 cm

Diagnosis:

Squamous Cell Carcinoma (NOS), partially basaloid

pT2a, pN0 (0/23), pMx, G3

Supplementary examination:

EGFR mutation analysis (sanger sequencing, Ex 18 – 21)

EGFR mutation positive

p.L856R (c.2573T>G)

Pathologist: [REDACTED]

[REDACTED]

Date:

Source: NCI Genomic Data Commons file 93d950a0-7492-4700-a3c2-913cbd20bb36 (TCGA-58-8392.D98BA859-91E2-4DE1-BB61-B925D77E33DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).